Surgical pathology report (de-identified scan), TCGA case TCGA-06-0743, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0743-01A (Primary Tumor).

[page 1 of 2]
TCGA-06-0743

Surgical Pathology Report

CLINICAL HISTORY

[REDACTED] with an episode of disorientation has a left parieto-occipital, enhancing tumor that on biopsy proved to be a glioblastoma. For total resection,

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, excision biopsy
B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, sites not specified, excision: Glioblastoma.
See Comment.

COMMENT

The tumor is an astrocytic neoplastic proliferation of small naked nuclei, abundantly fibrillary, with mitotic figures, microvascular cellular proliferation, and necrosis, some with pseudopalisading.

Special stains to better characterize the tumor have been requested and will be reported as an addendum..

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE - Methylated MGMT promoter is detected.

Results-Comments

Received were paraffin curls labeled [REDACTED]

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

[page 2 of 2]
FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

Interpretation

Brain, MIB-1 proliferation index: 12%.
See Results and Comment (below).

Results-Comments

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates gliofibrillogenesis by the neoplastic cells. About 8% of the tumor cells over express the p53 protein. With the MIB-1, there is a proliferation index of about 12% in the more active areas.

Comment: The immunophenotype is consistent with a high histological grade glial neoplasm.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

Brain, excision biopsy:

1. Frozen section: Glioma, 1 block, [REDACTED]
2. Smears: Glioma. [REDACTED]
- [REDACTED]

GROSS DESCRIPTION

A.

Multiple tissue fragments, 0.4 cm, all in A1, A2

B.

SPECIMEN: Brain tumor.

FIXATIVE: None.

GENERAL: Received is a 2.0 x 1.5 x 0.7 cm. irregular portion of tan-pink glistening, slightly convoluted tissue.

MAIN FINDING: The specimen is serially sectioned to reveal unremarkable cut surfaces.

SECTIONS: B1-B2 entirely submitted.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file cf668f35-1ae8-4287-bdd6-87a2b84f4f3e (TCGA-06-0743.E5A35D11-6D87-4D7E-AC41-73BFE35871FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).